Somatic mutation profile of tumor specimen MP2PRT-PAPEHK-TMP1-A (aliquot MP2PRT-PAPEHK-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPEHK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.9 years (2,150 days).
Specimen MP2PRT-PAPEHK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 647b1ec9-37d4-41ba-8c16-ecd780957a2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPEHK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPEHK-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d080fc6d-d3bc-4817-9624-a3229015a5f3

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 15, Silent 6, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 47/310 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 42/362 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- CBARP | c.944G>A p.R315H (on ENST00000382477; = p.R295H on NM_152769.3) | Missense Mutation (SNP) | VAF 209/434 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs769779150; called by muse, varscan2
- CSF1R | c.1716C>G p.N572K | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs772750557; called by muse, mutect2, varscan2
- ETV1 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 222/510 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs751525538, COSV54154308; called by muse, mutect2, varscan2
- H3-4 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 161/390 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs1482262254, COSV64211031; called by muse, mutect2, varscan2
- IL17D | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 23/515 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs909128552; called by muse, mutect2
- MRGPRF | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 276/570 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs775905409; called by muse, mutect2, varscan2
- NPC1 | c.3815G>A p.R1272H | Missense Mutation (SNP) | VAF 30/445 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.723); catalogued as rs563385810, COSV99340540; called by muse, mutect2
- OR2T2 | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 168/406 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs759070015; called by mutect2, varscan2
- PCDH10 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 38/532 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as rs1484989188, COSV52089616; called by muse, mutect2
- PROX1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 181/395 reads (46%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.98); catalogued as COSV54776187, COSV54785503; called by muse, mutect2, varscan2
- CASKIN1 | c.3967G>A p.A1323T | Missense Mutation (SNP) | VAF 23/309 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- COL22A1 | c.2821C>T p.L941F | Missense Mutation (SNP) | VAF 15/368 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0.037); called by muse, mutect2
- MUC2 | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 33/401 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2
- TRAJ16 | c.1_3delinsA p.S3Rfs*? | Frame Shift Del (DEL) | VAF 105/190 reads (55%) | called by pindel, varscan2*
- CTIF | c.1695G>A p.S565= | Silent (SNP) | VAF 184/450 reads (41%) | catalogued as rs774450377; called by muse, mutect2, varscan2
- GPR149 | c.69G>A p.T23= | Silent (SNP) | VAF 21/329 reads (6%) | catalogued as rs777546936, COSV101078479; called by muse, mutect2
- PCDH8 | c.840C>T p.D280= | Silent (SNP) | VAF 325/668 reads (49%) | catalogued as rs1321545050; called by muse, mutect2, varscan2
- SHISA9 | c.111C>T p.G37= | Silent (SNP) | VAF 35/674 reads (5%) | called by muse, mutect2
- TNXB | c.1371C>T p.S457= | Silent (SNP) | VAF 35/610 reads (6%) | catalogued as rs1469943517; called by muse, mutect2
- TTN | c.23088G>A p.P7696= (on ENST00000591111; = p.P6769= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 196/462 reads (42%) | catalogued as rs768390615, COSV59871983; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
